Somatic mutation profile of tumor specimen MMRF_2453_1_BM_CD138pos (aliquot MMRF_2453_1_BM_CD138pos_T1_KHS5U_L11227) from MMRF case MMRF_2453, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 58.5 years (21,380 days).
Specimen MMRF_2453_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f194e167-de1c-4623-ae2b-f82ceba56d85.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2453_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2453_1_PB_Whole_C3_KHS5U_L11228; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/903dd783-e806-4782-8a1c-79b06be29af6

The open-access MAF lists 94 somatic variants for this specimen: 35 protein-altering or splice-affecting, 15 silent, 44 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, 3'UTR 24, Silent 15, Intron 9, 5'UTR 4, RNA 3, 3'Flank 2, 5'Flank 2, Translation Start Site 1, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RYR1 | c.3535C>T p.R1179W | Missense Mutation (SNP) | VAF 111/373 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs763944786, CM123704; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ALKBH8 | c.857C>T p.S286F | Missense Mutation (SNP) | VAF 100/248 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99508648; called by muse, mutect2, varscan2
- CTAGE1 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 49/136 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.019); catalogued as rs372035129; called by muse, mutect2, varscan2
- CYP4Z1 | c.1120C>T p.R374C | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373398954; called by muse, mutect2, varscan2
- DNAH3 | c.1663G>A p.E555K | Missense Mutation (SNP) | VAF 43/79 reads (54%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs776747501, COSV54526929; called by muse, mutect2, varscan2
- IGHV2-70 | c.60G>C p.Q20H | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs374015637; called by muse, mutect2, varscan2
- JPH1 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 119/270 reads (44%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.926); catalogued as rs1482597158, COSV60611522; called by muse, mutect2, varscan2
- KIF1A | c.1238G>A p.R413H | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.859); catalogued as rs771678168, COSV57493219; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYC | c.437C>T p.S146L (on ENST00000377970; = p.S161L on NM_002467.6) | Missense Mutation (SNP) | VAF 146/360 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV52367052; called by muse, mutect2, varscan2
- NAALADL2 | c.901G>A p.A301T | Missense Mutation (SNP) | VAF 36/67 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs575644923, COSV69154945; called by muse, mutect2, varscan2
- PCSK6 | c.1507G>A p.V503M | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.695); catalogued as rs770089107; called by muse, mutect2, varscan2
- POLR1A | c.2395G>A p.V799M | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.218); catalogued as rs567699884, COSV55697776, COSV99808556; called by muse, mutect2, varscan2
- PPP2R2C | c.4C>T p.R2C | Missense Mutation (SNP) | VAF 95/219 reads (43%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs1240137510; called by muse, mutect2, varscan2
- SPTBN2 | c.5488C>T p.R1830C | Missense Mutation (SNP) | VAF 22/163 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1032630878, COSV59459989; called by muse, mutect2, varscan2
- WDR64 | c.2065G>C p.D689H | Missense Mutation (SNP) | VAF 116/313 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.596); catalogued as COSV63798062; called by muse, mutect2, varscan2
- WLS | c.1262G>A p.R421Q | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750244529, COSV52041671; called by muse, mutect2, varscan2
- ZNF142 | c.4744T>C p.C1582R (on ENST00000411696 / NM_001379660.1; = p.C1382R on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs761517709; called by muse, mutect2, varscan2
- ABCA13 | c.182A>G p.D61G | Missense Mutation (SNP) | VAF 46/131 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATM | c.8821T>A p.S2941T | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- CCDC8 | c.98A>T p.K33M | Missense Mutation (SNP) | VAF 89/325 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CD109 | c.1990T>G p.F664V | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CTNND2 | c.1629-1G>T p.X543_splice | Splice Site (SNP) | VAF 19/77 reads (25%) | called by muse, mutect2, varscan2
- CYP2E1 | c.1103T>C p.L368P | Missense Mutation (SNP) | VAF 69/168 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- DCAF10 | c.446C>G p.T149S | Missense Mutation (SNP) | VAF 85/344 reads (25%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- IGKV1-33 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 8/33 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.109); called by muse, varscan2
- LOXHD1 | c.2952G>T p.Q984H | Missense Mutation (SNP) | VAF 131/329 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- LRIG3 | c.1490C>T p.P497L | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MUC16 | c.40436T>C p.V13479A | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- MYC | c.436T>C p.S146P (on ENST00000377970; = p.S161P on NM_002467.6) | Missense Mutation (SNP) | VAF 148/364 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- RAB11FIP2 | c.1481G>T p.S494I | Missense Mutation (SNP) | VAF 164/424 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, varscan2
- SAMD1 | c.686_712del p.D229_D237del | In Frame Del (DEL) | VAF 38/244 reads (16%) | called by mutect2, varscan2
- SRRM3 | c.1584G>C p.K528N | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- TMEM102 | c.818C>T p.T273M | Missense Mutation (SNP) | VAF 74/171 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- USP25 | c.1393T>C p.C465R | Missense Mutation (SNP) | VAF 41/338 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF618 | c.2377A>G p.K793E (on ENST00000374126 / NM_001318042.2; = p.K700E on NM_133374.2) | Missense Mutation (SNP) | VAF 43/147 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- BARHL1 | c.291G>A p.L97= | Silent (SNP) | VAF 75/276 reads (27%) | called by muse, varscan2
- CLNK | c.417C>T p.S139= | Silent (SNP) | VAF 100/258 reads (39%) | catalogued as rs371671172; called by muse, varscan2
- DNAI3 | c.2013C>T p.H671= | Silent (SNP) | VAF 66/238 reads (28%) | catalogued as rs753481902; called by muse, mutect2, varscan2
- ESCO2 | c.60A>G p.L20= | Silent (SNP) | VAF 15/24 reads (63%) | called by muse, mutect2, varscan2
- ETS2 | c.1161C>T p.D387= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as rs765105270, COSV62874406; called by muse, mutect2, varscan2
- FAM189A1 | c.891G>A p.P297= | Silent (SNP) | VAF 29/100 reads (29%) | catalogued as rs746873946; called by muse, mutect2, varscan2
- IRGQ | c.649C>T p.L217= | Silent (SNP) | VAF 48/169 reads (28%) | called by muse, mutect2, varscan2
- LRP1B | c.10440A>G p.E3480= | Silent (SNP) | VAF 54/144 reads (38%) | called by muse, mutect2, varscan2
- MRC2 | c.558G>A p.P186= | Silent (SNP) | VAF 61/140 reads (44%) | catalogued as rs749206461; called by muse, mutect2, varscan2
- MYO15A | c.1272G>A p.P424= | Silent (SNP) | VAF 167/394 reads (42%) | catalogued as rs372551257; called by muse, mutect2, varscan2
- MYPOP | c.9G>A p.S3= | Silent (SNP) | VAF 20/38 reads (53%) | called by muse, mutect2, varscan2
- PKDREJ | c.1275C>T p.G425= | Silent (SNP) | VAF 57/125 reads (46%) | catalogued as rs377483844; called by muse, mutect2, varscan2
- PPP4R3C | c.1569A>G p.Q523= | Silent (SNP) | VAF 25/63 reads (40%) | called by muse, mutect2, varscan2
- SLC7A4 | c.1629C>T p.P543= | Silent (SNP) | VAF 25/73 reads (34%) | called by muse, mutect2, varscan2
- TCHP | c.595C>T p.L199= | Silent (SNP) | VAF 31/80 reads (39%) | called by muse, mutect2, varscan2
- AC078899.1 | n.666C>T | RNA (SNP) | VAF 87/265 reads (33%) | catalogued as rs1289342384; called by muse, mutect2, varscan2
- AMBN | c.*263C>A | 3'UTR (SNP) | VAF 43/104 reads (41%) | called by muse, mutect2, varscan2
- ANGPTL1 | c.*844T>C | 3'UTR (SNP) | VAF 22/40 reads (55%) | called by muse, mutect2, varscan2
- ARHGAP44 | c.*96C>T | 3'UTR (SNP) | VAF 28/57 reads (49%) | called by muse, mutect2, varscan2
- ARHGEF3 | c.*322A>G | 3'UTR (SNP) | VAF 30/69 reads (43%) | catalogued as rs548571132; called by muse, mutect2, varscan2
- ASTN1 | c.*505G>A | 3'UTR (SNP) | VAF 41/84 reads (49%) | called by muse, mutect2, varscan2
- BCL11A | c.*1939A>G | 3'UTR (SNP) | VAF 27/63 reads (43%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021402 C>T | 5'Flank (SNP) | VAF 38/108 reads (35%) | catalogued as rs925835724, COSV55846299, COSV55846759, COSV55847493; called by muse, mutect2, varscan2
- BRWD1 | c.6572-3828C>A | Intron (SNP) | VAF 34/146 reads (23%) | called by muse, mutect2, varscan2
- BTBD8 | c.*39A>G | 3'UTR (SNP) | VAF 16/96 reads (17%) | catalogued as rs765414549; called by muse, mutect2, varscan2
- CSMD2 | c.1326+5939G>A | Intron (SNP) | VAF 68/165 reads (41%) | called by muse, mutect2, varscan2
- CTPS1 | c.*9+44A>C | Intron (SNP) | VAF 125/307 reads (41%) | called by muse, mutect2, varscan2
- CXCL6 | c.*44C>T | 3'UTR (SNP) | VAF 24/319 reads (8%) | catalogued as rs374838254; called by muse, mutect2
- DCAF16 | c.*710T>C | 3'UTR (SNP) | VAF 24/54 reads (44%) | called by muse, mutect2, varscan2
- DNAJC19 | c.130-61G>T | Intron (SNP) | VAF 13/45 reads (29%) | called by muse, mutect2, varscan2
- EEF1AKMT2 | c.-19G>A | 5'UTR (SNP) | VAF 25/47 reads (53%) | catalogued as rs749330967; called by muse, mutect2, varscan2
- EGFR | c.2469+145C>G | Intron (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2
- ETV1 | c.*916T>C | 3'UTR (SNP) | VAF 24/67 reads (36%) | called by muse, mutect2, varscan2
- FEM1B | c.*4380T>C | 3'UTR (SNP) | VAF 34/113 reads (30%) | catalogued as rs904758580; called by muse, mutect2, varscan2
- GOLGA4 | c.*466dup | 3'UTR (INS) | VAF 22/73 reads (30%) | called by mutect2, pindel, varscan2
- HOMER1 | c.-542G>C | 5'UTR (SNP) | VAF 17/183 reads (9%) | called by muse, mutect2, varscan2
- IGHJ6 | chr14:105863448 G>A | 5'Flank (SNP) | VAF 4/14 reads (29%) | called by muse, varscan2
- LINC00955 | n.843T>C | RNA (SNP) | VAF 163/371 reads (44%) | catalogued as rs981443615; called by muse, varscan2
- LRAT | c.*3079G>A | 3'UTR (SNP) | VAF 4/72 reads (6%) | called by muse, mutect2
- MAP11 | c.-190C>A | 5'UTR (SNP) | VAF 29/122 reads (24%) | called by muse, mutect2, varscan2
- MEX3C | c.*1738A>T | 3'UTR (SNP) | VAF 15/43 reads (35%) | called by muse, mutect2, varscan2
- MFAP3 | c.*145A>G | 3'UTR (SNP) | VAF 68/113 reads (60%) | called by muse, mutect2, varscan2
- NLGN1 | c.*1007A>T | 3'UTR (SNP) | VAF 19/50 reads (38%) | called by muse, mutect2, varscan2
- NOX5 | c.*5125A>C | 3'UTR (SNP) | VAF 44/162 reads (27%) | called by muse, mutect2, varscan2
- PANX3 | c.*210A>G | 3'UTR (SNP) | VAF 9/103 reads (9%) | called by muse, mutect2
- PAX2 | c.*400del | 3'UTR (DEL) | VAF 22/55 reads (40%) | called by mutect2, pindel, varscan2
- PLK2 | c.*441dup | 3'UTR (INS) | VAF 27/106 reads (25%) | catalogued as rs373566097; called by mutect2, varscan2
- POF1B | c.*1102A>T | 3'UTR (SNP) | VAF 13/17 reads (76%) | called by muse, mutect2, varscan2
- POLRMT | c.-8C>T | 5'UTR (SNP) | VAF 15/51 reads (29%) | catalogued as rs764588095; called by muse, mutect2, varscan2
- PPP2R1B | c.1698-47T>C | Intron (SNP) | VAF 75/110 reads (68%) | catalogued as rs751669218; called by muse, mutect2
- RAB30 | chr11:82978009 del AAAGA | 3'Flank (DEL) | VAF 35/134 reads (26%) | called by mutect2, pindel, varscan2
- RABIF | c.*873T>C | 3'UTR (SNP) | VAF 44/120 reads (37%) | called by muse, mutect2, varscan2
- RBFOX1 | c.1071+510G>A | Intron (SNP) | VAF 88/263 reads (33%) | called by muse, mutect2, varscan2
- SECISBP2 | chr9:89364171 T>G | 3'Flank (SNP) | VAF 40/143 reads (28%) | called by muse, mutect2, varscan2
- SLC44A1 | c.*3911_*3912del | 3'UTR (DEL) | VAF 4/58 reads (7%) | catalogued as rs1359386098; called by pindel, varscan2
- SLC7A5P2 | n.165C>T | RNA (SNP) | VAF 14/56 reads (25%) | catalogued as rs780888351; called by muse, mutect2
- STK26 | c.*41G>T | 3'UTR (SNP) | VAF 219/309 reads (71%) | catalogued as COSV100049404; called by muse, mutect2, varscan2
- TRIM4 | c.919+1531C>T | Intron (SNP) | VAF 14/72 reads (19%) | catalogued as rs948968633; called by muse, mutect2, varscan2
- UBE3A | c.1617+25A>C | Intron (SNP) | VAF 121/217 reads (56%) | called by muse, mutect2, varscan2
